Surgical pathology report (de-identified scan), TCGA case TCGA-IR-A3LF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-IR-A3LF-01A (Primary Tumor).

[page 1 of 4]
Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral ovaries and bilateral tubes
- 2: SP: Rt. external iliac lymph node
- 3: SP: Rt. internal iliac lymph node (
- 4: SP: Rt. obturator lymph node
- 5: SP: Rt. common iliac lymph node (
- 6: SP: Lt. external iliac lymph node (
- 7: SP: Lt. internal iliac lymph node (
- 8: SP: Lt. obturator lymph node
- 9: SP: Lt. common iliac lymph node
- 10: SP: Lt. para-aortic lymph node (
- 11: SP: Rt. para-aortic lymph node (

DIAGNOSIS:

- 1) UTERUS, BILATERAL ADNEXA; HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- INVASIVE ADENOCARCINOMA OF UTERINE CERVIX, WITH ENDOMETRIOID FEATURES (SEE NOTE), MODERATELY DIFFERENTIATED.
- THE MAXIMAL THICKNESS OF THE CERVICAL STROMAL INVASION IS 6 MM.
- THE THICKNESS OF THE CERVIX IN THE AREA OF MAXIMAL TUMOR INVASION IS 20 MM.
- NO EVIDENCE OF TUMOR MULTICENTRICITY IS IDENTIFIED.
- IN SITU ENDOCERVICAL ADENOCARCINOMA IS ALSO PRESENT.
- NO VASCULAR INVASION IS IDENTIFIED.
- NO PERINEURAL INVASION IS IDENTIFIED.
- NO VAGINAL EXTENSION IS IDENTIFIED.
- THE TUMOR EXTENDS INTO THE LOWER UTERINE SEGMENT (MUCOSA AND STROMA).
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE ENDOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: ATROPHY.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITIES: ADENOMYOSIS AND LEIOMYOMA.
- ALL ADNEXAE ARE UNREMARKABLE.

NOTE: IMMUNOHISTOCHEMICAL STAINS SHOW THAT THE TUMOR CELLS ARE POSITIVE FOR CEA AND NEGATIVE FOR VIMENTIN, ER, AND PR, SUPPORTING A CERVICAL ORIGIN.

** Continued on next page **

ICD-0-3
CQC= adenocarcinoma, endocervical, mixed type 8384/3
Path adenocarcinoma, endometrioid, NOS 8380/3
Site: cervix, NOS C53.9
lw 12/21/11

Re-reviewed w/ mw DWG
Endocrine Tumor. OK.

[page 2 of 4]
-
- 2) LYMPH NODE, RIGHT EXTERNAL ILIAC; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 3) LYMPH NODE, RIGHT INTERNAL ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 4) LYMPH NODE, RIGHT OBTURATOR; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 5) LYMPH NODE, RIGHT COMMON ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 6) LYMPH NODE, LEFT EXTERNAL ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 7) LYMPH NODE, LEFT INTERNAL ILIAC; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 8) LYMPH NODE, LEFT OBTURATOR; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 9) LYMPH NODE, LEFT COMMON ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 10) LYMPH NODE, LEFT PARA-AORTIC; EXCISION:
- BENIGN FIBROUS TISSUE. (DEEPER SECTIONS PENDING).
- 11) LYMPH NODE, RIGHT PARA-AORTIC; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 3 of 4]
Procedures/Addenda:
Addendum

Addendum Diagnosis
ADDENDUM

** Continued on next page **

[page 4 of 4]
SITE: LEFT PARA-AORTIC LYMPH NODES, EXCISION
PART 10.

- ADDITIONAL DEEPER SECTIONS CONTAIN 3 BENIGN LYMPH NODES. THE FINAL
DIAGNOSIS FOR PART 10 IS:

PART 10: LEFT PARA-AORTIC LYMPH NODES, EXCISION:
3 BENIGN LYMPH NODES.

** End of Report **

Source: NCI Genomic Data Commons file dbb76a4d-88c8-4920-9694-a84ed783d666 (TCGA-IR-A3LF.8F0D0E63-D4E5-49A9-AC56-7D538284E917.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).